Somatic mutation profile of tumor specimen TCGA-78-8648-01A (aliquot TCGA-78-8648-01A-11D-2393-08) from TCGA case TCGA-78-8648, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 58.7 years (21,443 days).
Specimen TCGA-78-8648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c40ab9e-1aea-4e58-a3de-c656409e96f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-8648-10A (Blood Derived Normal), aliquot TCGA-78-8648-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bd51e0a-3c35-4343-88fd-e481ec420ded

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.1437-2A>T p.X479_splice | Splice Site (SNP) | VAF 6/141 reads (4%) | catalogued as COSV53052030, COSV99491395; called by muse, mutect2
- ELOVL3 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100892779; called by muse, mutect2
- GLB1 | c.1154T>G p.V385G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100257155, COSV56563982; called by muse, mutect2
- MAGEA3 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 16/401 reads (4%) | catalogued as rs1569459122; called by muse, mutect2
- RPRD2 | c.4342C>T p.P1448S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64818873, COSV64819428; called by muse, mutect2
- ANGPT1 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.109); called by muse, mutect2
- TAOK1 | c.2956A>T p.T986S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2
